Surgical pathology report (de-identified scan), TCGA case TCGA-57-1584, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-57-1584-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

Uterus, cervix, bilateral tubes and ovaries, hysterectomy:

Tumor Characteristics:

1. Histologic type: Serous papillary adenocarcinoma.
2. Grade: 3
3. Location: Ovary.
- a. Ovary involved: Bilateral
- b. Amount/degree of involvement of each ovary: Tumor involves all parts of both ovaries.
4. Lymphovascular space invasion: Yes.
5. Right fallopian tube: Normal
6. Left fallopian tube: Normal
7. Omentum involvement by tumor: Yes, grossly and microscopically largely nodule measures 0.5 cm following fixation and processing.
8. Other peritoneal biopsies:
- B. Left pelvic sidewall, biopsy:
Metastatic adenocarcinoma.

F. Colon implant, biopsy:

Metastatic adenocarcinoma.

Lymph Node Status:

C. Left pelvic lymph nodes, excision:

Number of lymph nodes examined: 2.

Number of lymph nodes containing metastatic carcinoma: 0 (0/2).

D. Left aortic lymph nodes, excision:

Number of lymph nodes examined: 7.

Number of lymph nodes containing metastatic carcinoma: 0 (0/7).

E. Right pelvic lymph nodes, excision:

Number of lymph nodes examined: 3.

NUMBER OF LYMPH NODES CONTAINING METASTATIC CARCINOMA 2 (2/3).

Microscopic subcapsular metastasis identified in 2 nodes.

G. Right aortic lymph nodes, excision:

Number of lymph nodes examined: 3.

Number of lymph nodes containing metastatic carcinoma: 0 (0/3).

Other:

1. Cervix: No significant histopathologic findings.
2. Endocervix: Negative for tumor involvement.

[page 2 of 3]
3. Endometrium: Proliferative endometrium.
4. Myometrium: Superficial adenomyosis.
5. Uterine serosa: Serosal adhesions without evidence of metastatic carcinoma.
6. Other organs or biopsies: Vermiform appendix demonstrating no significant histopathologic changes.
7. pTNM stage: T2bN1MX.

COMMENTS:

This case has been reviewed in intradepartmental consultation and as part of the Department's Quality Review Program by [REDACTED] who is in agreement with the diagnosis.

CLINICAL HISTORY:

Preoperative Diagnosis: Malignant neoplasm ovary

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Uterus, cervix, bilateral tubes and ovaries (tissue study)
- B. Left pelvic sidewall
- C. Left pelvic lymph nodes
- D. Left aortic nodes
- E. Right pelvic lymph nodes
- F. Colon implant
- G. Right aortic nodes
- H. Appendix
- I. Omentum

GROSS DESCRIPTION:

A. Part A received in formalin labeled [REDACTED] and #1 uterus, cervix, bilateral tubes and ovaries is a 114 gram hysterectomy specimen, consisting of a 6.8 x 4.3 x 3.2 cm uterine body and a 3.2 x 2.5 x 2.3 cm cervix, with attached bilateral adnexa. The serosa is smooth and tan pink. The exocervix is smooth and gray white with a 0.6 cm slit-like os. The endocervical canal is tan and 2.1 cm in length. The endometrial cavity is 1.4 cm from cornu to cornu and 4.8 cm in length. The endometrium is glistening tan, focally hemorrhagic, and averages 0.3 cm in thickness. The myometrium is trabeculated, tan pink, and averages 1.8 cm in thickness.

The 9.2 x 6.7 x 3.6 cm left ovary has an attached 6.4 x 0.2 cm fimbriated left fallopian tube. The outer surface of the ovary is smooth to lobulated and tan pink to purple. The cut surface consists of focally cystic gray white soft tissue. There are focal areas of yellow lined corpora luteal cysts. The fallopian tube has a tan pink serosa and a pinpoint lumen. The 11.8 x 7.1 x 3.7 cm right ovary has a minimal amount of attached possible fallopian tube. The outer surface is smooth to lobulated and tan pink. The cut surface consists of focally cystic gray white soft tissue with a minimal amount of yellow lined corpora luteal cysts. The fallopian tube has a tan pink serosa and a pinpoint lumen.

The specimen is serially sectioned and representative sections are submitted as labeled: 1—anterior cervix, posterior cervix—2; 3—anterior endomyometrium with serosa; 4—posterior endomyometrium with serosa; 5—left fallopian tube; 6 to 9—left ovary; 10—right ovary and fallopian tube; 11 to 13—right ovary. The blocks are labeled [REDACTED].

Also received in the same container is a green and yellow cassette labeled [REDACTED] for genomic research study. ✓

B. Part B received in formalin labeled [REDACTED] #2 left pelvic sidewall is a 1.7 x 1.1 x 0.3 cm irregular, shaggy tan red soft tissue, which is serially sectioned and submitted in its entirety in one cassette labeled [REDACTED].

C. Part C received in formalin labeled [REDACTED] and #3 left pelvic lymph nodes is a 4.8 x 2.6 x 0.6 cm irregular fibroadipose tissue, bearing two irregular tan yellow firm tissues, consistent with probable lymph nodes, measuring 0.6 x 0.2 x 0.1 cm and 3.8 x 0.7 x 0.4 cm. The specimen is sectioned and representative sections are submitted, to include the lymph nodes in their entirety, as labeled: 1—one whole probable lymph node, 2 and 3—one lymph node, serially sectioned. The blocks are labeled [REDACTED].

D. Part D received in formalin labeled [REDACTED] and #4 left aortic nodes is a 4.3 x 2.1 x 0.8 cm aggregate of fibroadipose tissue, bearing multiple

[page 3 of 3]
irregular tan yellow firm tissues, consistent with probable lymph nodes, ranging from 0.4 x 0.2 x 0.1 cm to 1.6 x 0.4 x 0.2 cm. The specimen is sectioned and representative sections are submitted, to include the lymph nodes in their entirety, as labeled: 1—three whole probable lymph nodes; 2—two whole probable lymph nodes; 3 and 4—one lymph node, bisected in each. The blocks are labeled [REDACTED]

E. Part E received in formalin labeled [REDACTED] and #5 right pelvic lymph nodes is a 3.7 x 2.6 x 0.7 cm aggregate of fibroadipose tissue, bearing three irregular tan yellow firm tissues, consistent with probable lymph nodes, ranging from 0.7 x 0.6 x 0.5 cm to 2.3 x 1.3 x 0.4 cm. The specimen is sectioned and representative sections are submitted, to include the lymph nodes in their entirety, as labeled: 1 to 3—one lymph node, bisected in each. The blocks are labeled [REDACTED]

F. Part F received in formalin labeled [REDACTED] and #6 colon implant is a 2.6 x 2.3 x 0.7 cm aggregate of fibroadipose tissue. The cut surface consists of focal gray white areas. The specimen is serially sectioned and representative sections are submitted in three cassettes labeled [REDACTED]

G. Part G received in formalin labeled [REDACTED] and #7 right aortic nodes is a 2.8 x 1.4 x 0.4 cm irregular fibroadipose tissue, bearing three irregular tan pink soft tissues, consistent with probable lymph nodes, ranging from 0.6 x 0.5 x 0.2 cm to 1.7 x 1.2 x 0.4 cm. The specimen is sectioned and representative sections are submitted, to include the lymph nodes in their entirety, as labeled: 1—two whole probable lymph nodes; 2—one lymph node, bisected. The blocks are labeled [REDACTED]

H. Part H received in formalin labeled [REDACTED] and #8 appendix is a 6.5 x 0.5 x 0.4 cm appendix, with attached adipose tissue. The serosa is smooth and tan pink with gray white nodules near the distal tip. The mucosa is smooth and tan. The lumen averages 0.1 cm and contains a green substance. The wall thickness averages 0.1 cm. The specimen is serially sectioned, the proximal margin is inked, and representative sections are submitted in one cassette labeled [REDACTED]

I. Part I received in formalin labeled [REDACTED] and #9 omentum is a 50.6 x 12.8 x 0.8 cm irregular fibroadipose tissue, consistent with omentum. The cut surface consists of predominantly yellow lobulated adipose tissue with a minimal amount of gray white fibrous tissue. There are small focal gray white nodules on the cut surface. The specimen is serially sectioned and representative sections are submitted in one cassette labeled [REDACTED]

Source: NCI Genomic Data Commons file 049ffb52-3b37-4e90-a13f-8efad7cd9ab2 (TCGA-57-1584.3E4B484E-4727-444F-B2BC-C32D5D1AD815.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).